Somatic mutation profile of tumor specimen TCGA-D3-A8GJ-06A (aliquot TCGA-D3-A8GJ-06A-11D-A372-08) from TCGA case TCGA-D3-A8GJ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 25.5 years (9,316 days).
Specimen TCGA-D3-A8GJ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2514b6b0-3242-4526-a061-6da4c60e461b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GJ-10A (Blood Derived Normal), aliquot TCGA-D3-A8GJ-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87329e23-87a5-4fdb-9a0e-33e090687a0a

The open-access MAF lists 242 somatic variants for this specimen: 140 protein-altering or splice-affecting, 93 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 93, Nonsense Mutation 8, Intron 4, Splice Site 2, 5'UTR 2, Splice Region 2, 3'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- OAT | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs121965051, CM920519; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACE | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52011950; called by muse, mutect2, varscan2
- ADAM28 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV99737724; called by muse, mutect2, varscan2
- ADAM32 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1421726511, COSV101165245; called by muse, mutect2, varscan2
- ADGRV1 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV101315489; called by muse, mutect2, varscan2
- ADH1C | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs774092660, COSV72463676; called by muse, mutect2, varscan2
- ADH7 | c.807G>A p.M269I | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV99265049; called by muse, mutect2, varscan2
- ALS2 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV99968741; called by muse, mutect2, varscan2
- ANKZF1 | c.1692-2A>G p.X564_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | catalogued as COSV99850238; called by muse, mutect2, varscan2
- AOAH | c.971G>A p.W324* | Nonsense Mutation (SNP) | VAF 29/161 reads (18%) | catalogued as COSV51735711; called by muse, mutect2, varscan2
- AP2B1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV52003439, COSV99250918; called by muse, mutect2, varscan2
- BCAT1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53915744; called by muse, mutect2, varscan2
- BEND4 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101549712; called by muse, mutect2, varscan2
- C19orf73 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV55522516; called by muse, mutect2, varscan2
- C1S | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100196361; called by muse, mutect2, varscan2
- C4A | c.2802G>A p.E934= | Splice Region (SNP) | VAF 4/34 reads (12%) | catalogued as rs1188992823, COSV101418297; called by mutect2, varscan2
- CAMTA1 | c.2486G>A p.G829D | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV100346221; called by muse, mutect2, varscan2
- CARD11 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100712204; called by muse, mutect2, varscan2
- CARD11 | c.221-1G>A p.X74_splice | Splice Site (SNP) | VAF 31/158 reads (20%) | catalogued as COSV100712205, COSV62717315; called by muse, mutect2, varscan2
- CBX3 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100522843; called by muse, mutect2, varscan2
- CCNL1 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as COSV99904385; called by muse, mutect2, varscan2
- CDH2 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.935); catalogued as COSV99295656; called by muse, mutect2, varscan2
- CEP152 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.238); catalogued as COSV100358481; called by muse, mutect2, varscan2
- CERKL | c.1369C>T p.L457F (on ENST00000339098 / NM_001030311.2; = p.L431F on NM_201548.5) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100183124; called by muse, mutect2, varscan2
- CMYA5 | c.1649A>G p.H550R | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs778505660, COSV101483829; called by muse, mutect2, varscan2
- CNR1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759148; called by muse, mutect2, varscan2
- DAZL | c.752G>T p.S251I | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV51712846, COSV99167465; called by muse, mutect2, varscan2
- DDOST | c.592C>T p.R198* (on ENST00000415136; = p.R181* on NM_005216.5) | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as rs747589765, COSV100387146; called by muse, mutect2, varscan2
- DISC1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV99697129; called by muse, mutect2
- DKKL1 | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55563888, COSV99678593; called by muse, mutect2
- DSG1 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as rs755271644, COSV99935571; called by muse, mutect2, varscan2
- DSPP | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.042); catalogued as COSV99216384; called by muse, mutect2, varscan2
- ENAM | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); catalogued as COSV68537068; called by muse, mutect2, varscan2
- EPHB6 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs760385897, COSV63892078; called by muse, mutect2, varscan2
- ERN2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV56833909, COSV56838093; called by muse, mutect2, varscan2
- FGGY | c.758C>A p.A253E | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs778888699, COSV100363762, COSV58037805; called by muse, mutect2, varscan2
- FSCN3 | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV99756783; called by muse, mutect2, varscan2
- GABRG1 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.088); catalogued as COSV99777377; called by muse, mutect2
- GALNT3 | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1435975151, COSV101204879; called by muse, mutect2, varscan2
- GALNT5 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs758078817, COSV52040004; called by muse, mutect2, varscan2
- GEM | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99891072; called by muse, mutect2, varscan2
- GHR | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV50125042; called by mutect2, varscan2
- GLB1L3 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV101110979; called by muse, mutect2, varscan2
- GRAMD2B | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99586944; called by muse, mutect2, varscan2
- GRXCR1 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV67669914; called by muse, mutect2, varscan2
- GTF2F1 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV101081049; called by muse, mutect2, varscan2
- HAO2 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 36/182 reads (20%) | catalogued as rs764148838, COSV58038827; called by muse, mutect2, varscan2
- HECTD1 | c.3130T>C p.Y1044H | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV101237300; called by muse, mutect2, varscan2
- HHIP | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99666574; called by muse, mutect2, varscan2
- HIC1 | c.142G>A p.D48N (on ENST00000322941 / NM_001098202.1; = p.D29N on NM_006497.4) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99557760; called by muse, mutect2, varscan2
- HIVEP1 | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV101044687; called by muse, mutect2, varscan2
- HPGDS | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as COSV99755489; called by muse, mutect2, varscan2
- HYAL4 | c.1012A>G p.I338V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs769950142, COSV99772051; called by muse, mutect2, varscan2
- JAM2 | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV100467814; called by muse, mutect2, varscan2
- KCNK6 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs151147940, COSV99649257; called by muse, mutect2, varscan2
- KCNK9 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs866844688, COSV100270337, COSV57288925; called by muse, mutect2, varscan2
- KIF22 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV99360835; called by muse, mutect2, varscan2
- KLKB1 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778280069, COSV52997876; called by muse, mutect2, varscan2
- KMT2C | c.11762C>G p.A3921G | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100066642; called by muse, mutect2, varscan2
- LMOD2 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV101505408; called by muse, mutect2, varscan2
- LRBA | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100840926, COSV100840963; called by muse, mutect2, varscan2
- MAP3K19 | c.3920G>A p.R1307K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100208047; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3661C>T p.P1221S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1177846665, COSV99167660; called by muse, mutect2, varscan2
- MUC16 | c.4402G>A p.E1468K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs267605810, COSV67493443; called by muse, mutect2, varscan2
- MYH1 | c.3922G>A p.G1308S | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99874878; called by muse, mutect2, varscan2
- NDST4 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as rs1419125683, COSV52135440; called by muse, mutect2, varscan2
- NFXL1 | c.2423A>T p.E808V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV101039996; called by muse, mutect2, varscan2
- NLRP4 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100015586, COSV56709094; called by muse, mutect2, varscan2
- NLRP5 | c.3051G>A p.M1017I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV66765557; called by muse, mutect2, varscan2
- NOX4 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.135); catalogued as rs778950581, COSV99629573; called by muse, mutect2, varscan2
- OR2B2 | c.449T>G p.I150S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV100308036, COSV57579581; called by muse, mutect2, varscan2
- OR2T27 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100788113; called by muse, mutect2, varscan2
- OR4C12 | c.743T>A p.F248Y | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.182); catalogued as COSV100078259; called by muse, mutect2, varscan2
- OR4N5 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs771871827, COSV100374012; called by muse, mutect2, varscan2
- OR52E2 | c.248T>A p.M83K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100384628; called by muse, mutect2, varscan2
- OR6T1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV58306859, COSV58308509; called by muse, mutect2, varscan2
- OR7E24 | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV101509634; called by muse, mutect2, varscan2
- ORC1 | c.1906C>T p.L636F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760700296, COSV100856583, COSV65363886; called by muse, mutect2, varscan2
- PANK3 | c.1045T>G p.L349V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99496180; called by muse, mutect2, varscan2
- PDE4B | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100302211; called by muse, mutect2, varscan2
- PDZD8 | c.3212C>T p.S1071L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100041341; called by muse, mutect2, varscan2
- PGD | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs562944056, COSV54620971; called by muse, mutect2, varscan2
- PIK3R2 | c.1064G>C p.R355P | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717185; called by muse, mutect2, varscan2
- PLB1 | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577566; called by muse, mutect2, varscan2
- PLCB4 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs1309835742, COSV99594343; called by muse, mutect2, varscan2
- PLCB4 | c.2958G>A p.K986= | Splice Region (SNP) | VAF 15/35 reads (43%) | catalogued as COSV53824704; called by muse, mutect2
- PLEKHG4B | c.1534G>A p.E512K (on ENST00000283426; = p.E868K on NM_052909.5) | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99359780; called by muse, mutect2, varscan2
- POMK | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100505661; called by muse, mutect2, varscan2
- PPP1CB | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 49/225 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV99941677; called by muse, mutect2, varscan2
- PRAMEF4 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 91/447 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs1411748055, COSV52438052, COSV99339448; called by muse, mutect2, varscan2
- PRKCB | c.1260G>A p.M420I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100332248; called by muse, mutect2, varscan2
- RAPGEF2 | c.1628G>A p.S543N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV100030503; called by muse, mutect2, varscan2
- RAPH1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs193223010, COSV57356659; called by muse, mutect2, varscan2
- RBFOX1 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360969688, COSV100299560; called by muse, varscan2
- RELN | c.9088G>A p.G3030R | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs763013239, COSV58989320; called by muse, mutect2, varscan2
- RGS7 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.809); catalogued as rs1193619517, COSV100464607; called by muse, mutect2, varscan2
- RIDA | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54704656; called by muse, mutect2, varscan2
- RP1 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV55113016; called by muse, mutect2, varscan2
- RPN1 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99956860; called by muse, mutect2, varscan2
- RPRD2 | c.3523C>T p.Q1175* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV100954888; called by muse, mutect2, varscan2
- RSPH14 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs767194293, COSV99320409; called by muse, mutect2, varscan2
- SCAMP2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222252432, COSV99173922; called by muse, mutect2, varscan2
- SCN11A | c.1671G>A p.W557* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as rs1553638676, COSV56580237; called by muse, mutect2, varscan2
- SEMG2 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV65647263, COSV65647834; called by muse, mutect2, varscan2
- SERPINB7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs756029823, COSV100320421, COSV60534448; called by muse, mutect2, varscan2
- SLC15A2 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 72/389 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99815081; called by muse, mutect2, varscan2
- SLC26A3 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.868); catalogued as rs923181529, COSV60640273; called by muse, mutect2, varscan2
- SPATA31A1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as rs1212818988; called by mutect2, varscan2
- STARD6 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV100323358; called by muse, mutect2, varscan2
- STYXL2 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54807466; called by muse, mutect2, varscan2
- SYNE2 | c.19438C>T p.P6480S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs753827351, COSV100646656; called by muse, mutect2, varscan2
- TACC3 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100508476; called by muse, mutect2, varscan2
- TAF1L | c.5354C>T p.P1785L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs764448670, COSV54259198, COSV54267694; called by muse, mutect2, varscan2
- THSD7B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752809070, COSV55657303; called by muse, mutect2, varscan2
- THSD7B | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765978646, COSV99744293; called by muse, mutect2, varscan2
- TINAG | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs776117214, COSV52510057, COSV99448496; called by muse, mutect2, varscan2
- TLDC2 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99455700; called by muse, mutect2, varscan2
- TM7SF3 | c.1589A>G p.N530S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV100544621; called by muse, mutect2, varscan2
- TRANK1 | c.4297C>T p.R1433C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748404500, COSV100081449; called by muse, mutect2, varscan2
- TRHDE | c.3055G>A p.G1019R | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755814569, COSV53848977; called by muse, mutect2, varscan2
- TRIM21 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); catalogued as COSV99587475; called by muse, mutect2, varscan2
- TRIM58 | c.794A>G p.E265G | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100824872; called by muse, mutect2, varscan2
- TTN | c.69170G>A p.S23057N (on ENST00000591111; = p.S15633N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | PolyPhen probably damaging (0.988); catalogued as rs769515743, COSV100593874; called by muse, mutect2, varscan2
- TTN | c.20066G>A p.R6689K (on ENST00000591111; = p.R5762K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | PolyPhen benign (0); catalogued as rs771200026, COSV60386317; called by muse, mutect2, varscan2
- UBP1 | c.822G>A p.M274I | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.026); catalogued as COSV99372479; called by muse, mutect2, varscan2
- UBR1 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.038); catalogued as COSV99316630; called by muse, mutect2, varscan2
- UBR4 | c.4230C>G p.I1410M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100920199; called by muse, mutect2, varscan2
- UNC13C | c.6527C>T p.S2176F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs372932752; called by muse, mutect2, varscan2
- USH2A | c.9557C>T p.S3186F | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV100228896; called by muse, mutect2, varscan2
- WHRN | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV99469773; called by muse, mutect2, varscan2
- ZFAT | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV100914222; called by muse, mutect2, varscan2
- ZIM2 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99687236; called by muse, mutect2, varscan2
- ZNF117 | c.1422A>T p.K474N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1256004031, COSV99275179; called by muse, mutect2, varscan2
- ZNF565 | c.1373C>T p.P458L (on ENST00000355114; = p.P418L on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100411752; called by muse, mutect2, varscan2
- ZNF578 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs1444129067, COSV101405005; called by muse, mutect2, varscan2
- ZNF804B | c.3781A>T p.T1261S | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as COSV100301742, COSV60853374; called by muse, mutect2, varscan2
- PRAMEF19 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- RBP3 | c.3604G>A p.D1202N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABHD4 | c.315C>T p.F105= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs200721495, COSV53530924; called by muse, mutect2, varscan2
- AFDN | c.4194G>A p.G1398= | Silent (SNP) | VAF 52/100 reads (52%) | catalogued as rs773812168, COSV100652443; called by muse, mutect2, varscan2
- AGBL1 | c.3159C>T p.L1053= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs371637847; called by muse, mutect2, varscan2
- AHNAK | c.471C>T p.V157= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV99945523; called by muse, mutect2, varscan2
- AKAP6 | c.5142G>A p.S1714= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs1178024502, COSV55206312; called by muse, mutect2, varscan2
- ALDH18A1 | c.288A>T p.A96= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100973057; called by muse, mutect2, varscan2
- AMPD2 | c.2301C>T p.T767= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99857334; called by muse, mutect2, varscan2
- ANXA2 | c.369C>G p.T123= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV100221871; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1068C>T p.F356= | Silent (SNP) | VAF 35/205 reads (17%) | catalogued as COSV100376809; called by muse, mutect2, varscan2
- BEND2 | c.1017C>T p.F339= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV66215042; called by muse, mutect2, varscan2
- BPIFB2 | c.951G>A p.K317= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99401130; called by muse, mutect2
- C1orf94 | c.1329C>T p.F443= (on ENST00000488417 / NM_001134734.2; = p.F253= on NM_032884.5) | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100974666; called by muse, mutect2, varscan2
- CACNA1H | c.993C>A p.G331= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs770821118, COSV100670762, COSV62000679; ClinVar: benign; called by muse, mutect2, varscan2
- CACNG3 | c.351C>T p.F117= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs774241889, COSV50064207; called by muse, mutect2, varscan2
- CALB2 | c.606G>A p.A202= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as rs756965535, COSV56940486; called by muse, mutect2, varscan2
- CCDC74A | c.897C>T p.L299= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99723548; called by muse, mutect2, varscan2
- CDH18 | c.294G>A p.G98= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as rs757076706, COSV56926593; called by muse, mutect2, varscan2
- CER1 | c.324G>A p.G108= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV101097757; called by muse, mutect2, varscan2
- CHRM5 | c.1245G>A p.T415= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs139260673; called by muse, mutect2, varscan2
- CNOT4 | c.1992C>T p.I664= (on ENST00000541284 / NM_001190850.1; = p.I590= on NM_013316.4) | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as rs1563005652, COSV64156858; called by muse, mutect2, varscan2
- CXADR | c.999G>A p.P333= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs759177936, COSV99515003; called by muse, mutect2, varscan2
- CYP4F12 | c.1158G>A p.K386= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV100215606, COSV100215776; called by muse, mutect2, varscan2
- DZIP3 | c.1506C>A p.I502= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100847622; called by muse, mutect2, varscan2
- EIF4G1 | c.2638C>T p.L880= (on ENST00000346169 / NM_198241.3; = p.L685= on NM_004953.5) | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV100071423; called by muse, mutect2, varscan2
- EIF5B | c.2739A>G p.L913= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99176802; called by muse, mutect2, varscan2
- EPB41L1 | c.1974C>T p.S658= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99148911; called by muse, mutect2, varscan2
- EPHB6 | c.1572C>T p.L524= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100844120; called by muse, mutect2, varscan2
- F10 | c.1188C>T p.F396= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100979139; called by muse, mutect2, varscan2
- GAL3ST1 | c.774G>A p.S258= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as rs1467884299, COSV100142914; called by muse, mutect2, varscan2
- GBA | c.1236C>T p.Y412= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100516219; called by muse, mutect2, varscan2
- GREB1 | c.4245C>T p.H1415= | Silent (SNP) | VAF 91/426 reads (21%) | catalogued as rs758770437, COSV99302217; called by muse, mutect2, varscan2
- HAS2 | c.543C>T p.I181= | Silent (SNP) | VAF 132/468 reads (28%) | catalogued as COSV100391445; called by muse, mutect2, varscan2
- HLA-DPB1 | c.468C>T p.V156= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs772223745, COSV69603364; called by muse, mutect2, varscan2
- HRH1 | c.726G>A p.E242= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101229035; called by muse, mutect2, varscan2
- HS3ST4 | c.1353G>A p.Q451= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV58830111; called by muse, mutect2
- HTR1E | c.57C>T p.I19= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100540933; called by muse, mutect2, varscan2
- IGF2BP2 | c.741C>T p.T247= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV100648837; called by muse, mutect2, varscan2
- ISYNA1 | c.1302C>T p.T434= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1433063041, COSV99525946; called by muse, mutect2, varscan2
- KALRN | c.4554G>A p.T1518= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs375540748, COSV53752897; called by muse, mutect2, varscan2
- KDM7A | c.486C>T p.V162= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs1391620089, COSV99133930; called by muse, mutect2, varscan2
- KHDC3L | c.219G>A p.L73= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV100951061; called by muse, mutect2, varscan2
- KMT2A | c.954C>T p.L318= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100627972; called by muse, mutect2, varscan2
- KRT4 | c.588G>A p.R196= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV53410977; called by muse, mutect2, varscan2
- LAMA2 | c.6546C>T p.L2182= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as COSV101370005; called by muse, mutect2, varscan2
- MAGEB6B | c.957G>A p.G319= | Silent (SNP) | VAF 44/114 reads (39%) | called by muse, mutect2, varscan2
- MARCHF4 | c.741C>T p.F247= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV56109347; called by muse, mutect2, varscan2
- MUC16 | c.17394G>A p.E5798= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV101198085; called by muse, mutect2, varscan2
- MUC16 | c.8466C>T p.N2822= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs777062505, COSV101198086; called by muse, mutect2, varscan2
- MUC17 | c.2946G>A p.T982= | Silent (SNP) | VAF 100/394 reads (25%) | catalogued as rs777986047, COSV60288895; called by muse, mutect2, varscan2
- MYO1F | c.2784G>A p.K928= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs773206689, COSV100596591, COSV57795521; called by muse, mutect2, varscan2
- NLRP4 | c.2463C>T p.D821= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs187474950; called by muse, mutect2, varscan2
- NOL4 | c.1392G>A p.K464= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV99305027; called by muse, mutect2, varscan2
- NPAP1 | c.285G>A p.R95= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV61510930; called by muse, mutect2, varscan2
- OR10Z1 | c.879G>A p.R293= | Silent (SNP) | VAF 123/338 reads (36%) | catalogued as rs781215502, COSV63525122; called by muse, mutect2, varscan2
- OR1L4 | c.472C>T p.L158= | Silent (SNP) | VAF 32/250 reads (13%) | catalogued as COSV99413773, COSV99413863; called by muse, varscan2
- OR51E1 | c.183C>T p.P61= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs763273730, COSV101211462; called by muse, mutect2, varscan2
- OR8I2 | c.339C>T p.F113= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV56167742; called by muse, mutect2, varscan2
- PANK4 | c.1269G>A p.P423= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs201279461, COSV101022301; called by muse, mutect2, varscan2
- PAPPA2 | c.1860C>T p.S620= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1456395525, COSV100866536; called by muse, mutect2, varscan2
- PCDH18 | c.1080C>T p.S360= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1170531397, COSV61268782; called by muse, mutect2, varscan2
- PCLO | c.15312G>A p.G5104= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs267601582, COSV61629858; called by muse, mutect2
- PLS1 | c.1260C>T p.D420= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100537949; called by muse, mutect2
- PPP2R3B | c.456C>T p.F152= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs759650886, COSV66814577; called by muse, mutect2, varscan2
- PRAMEF19 | c.66C>T p.A22= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- PROM2 | c.96C>T p.F32= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100468639; called by mutect2, varscan2
- RIMBP2 | c.1746C>T p.P582= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1196751965, COSV99898310; called by muse, mutect2
- RTL3 | c.276G>A p.Q92= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs747741103, COSV100329516, COSV58185682; called by muse, mutect2, varscan2
- SCN10A | c.4650C>T p.S1550= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV101479236; called by muse, mutect2, varscan2
- SERPINA9 | c.117C>T p.T39= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100097861; called by muse, mutect2, varscan2
- SERPINB9 | c.1065C>T p.F355= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs767287819, COSV66234313; called by muse, mutect2, varscan2
- SIPA1L1 | c.2214C>T p.I738= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs778418667, COSV100665115; called by muse, mutect2, varscan2
- SLC4A1AP | c.855C>T p.S285= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs779719870, COSV58137945; called by muse, mutect2, varscan2
- SLC9A4 | c.393C>T p.F131= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1434692166, COSV54839148; called by muse, mutect2, varscan2
- SLCO5A1 | c.2241C>T p.F747= | Silent (SNP) | VAF 82/225 reads (36%) | catalogued as rs1294938615, COSV52655710; called by muse, mutect2, varscan2
- SOS2 | c.1281C>T p.I427= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs8010578, COSV99365397; called by muse, mutect2, varscan2
- SPTA1 | c.1884G>A p.K628= | Silent (SNP) | VAF 26/288 reads (9%) | catalogued as COSV100934225, COSV63749312; called by muse, mutect2
- TAF1L | c.2778C>T p.S926= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as COSV54258673, COSV99644089; called by muse, mutect2, varscan2
- TAFA2 | c.255G>A p.V85= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV101352876; called by muse, mutect2, varscan2
- TAS2R7 | c.579C>T p.P193= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99553555; called by muse, mutect2, varscan2
- TF | c.597C>T p.S199= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV99395374; called by muse, mutect2, varscan2
- TIMP1 | c.522C>T p.L174= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs919546295, COSV99512090; called by muse, mutect2, varscan2
- TMC5 | c.72C>T p.N24= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs753109775, COSV66866855; called by muse, mutect2, varscan2
- TNFSF15 | c.735C>T p.F245= | Silent (SNP) | VAF 28/172 reads (16%) | catalogued as COSV100928303, COSV65010155; called by muse, mutect2, varscan2
- TPST2 | c.534C>T p.F178= | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as COSV58682172; called by muse, mutect2, varscan2
- TRIML1 | c.243C>T p.L81= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs753740188, COSV100205701; called by muse, mutect2, varscan2
- TTC3 | c.3175C>A p.R1059= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as rs1327717237, COSV100694999; called by muse, mutect2, varscan2
- UGT2B7 | c.1245G>A p.V415= | Silent (SNP) | VAF 37/180 reads (21%) | catalogued as COSV100535104; called by muse, mutect2, varscan2
- UNC13C | c.1161G>A p.R387= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1566949661, COSV52855420, COSV52891225; called by muse, mutect2, varscan2
- UPB1 | c.681G>A p.R227= | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs1347848752, COSV100387060; called by muse, mutect2, varscan2
- USP7 | c.2985C>T p.F995= | Silent (SNP) | VAF 139/369 reads (38%) | catalogued as COSV61214063; called by muse, mutect2, varscan2
- WNT10B | c.558C>T p.P186= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99975723; called by muse, mutect2, varscan2
- ZFYVE26 | c.4173C>T p.L1391= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100720069; called by muse, mutect2, varscan2
- ZNF560 | c.1734G>A p.G578= | Silent (SNP) | VAF 39/170 reads (23%) | catalogued as rs1171623317, COSV100038220, COSV100039007; called by muse, mutect2, varscan2
- FREM1 | c.4857+1674G>A | Intron (SNP) | VAF 26/124 reads (21%) | catalogued as COSV66518605; called by muse, mutect2, varscan2
- FRG2 | c.-2A>G | 5'UTR (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1286G>A | RNA (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- NTM | c.-1C>T | 5'UTR (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100867362; called by muse, mutect2
- RN7SL484P | chr15:99791792 A>T | 3'Flank (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23843G>A | Intron (SNP) | VAF 9/64 reads (14%) | catalogued as COSV67441932; called by muse, mutect2, varscan2
- TRIM8 | c.*282G>A | 3'UTR (SNP) | VAF 35/111 reads (32%) | catalogued as rs1249172552, COSV100193044; called by muse, mutect2, varscan2
- TTN | c.10360+4462C>T | Intron (SNP) | VAF 21/135 reads (16%) | catalogued as COSV100593878, COSV60045210; called by muse, mutect2, varscan2
- TTN | c.10360+1265A>C | Intron (SNP) | VAF 49/219 reads (22%) | catalogued as COSV100593880; called by muse, mutect2, varscan2
